TCGA case TCGA-C5-A8YR — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/be8b1c78-8cb1-4bff-b1fe-71ecdc454c94

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 837 days (2.3 years).

Diagnoses (2)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 56.6 years (20,672 days); Year of diagnosis: 1994; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 29.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, large cell, nonkeratinizing, NOS). Age at diagnosis: 57.3 years (20,944 days); Days to diagnosis: 272 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 272 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 272 days.
- Follow-up contact recording only the day: day 837.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Pregnant at diagnosis: No.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A8YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 50 mg.
  Slide TCGA-C5-A8YR-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample TCGA-C5-A8YR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Live birth pregnancy count: 4; Pregnancies count miscarriage: 2; Total pregnancy count: 6; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 837 days; disease-specific survival: event status not recorded, 837 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 272 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A8YR-01A-12D-A37M-01): tumor purity 0.79, ploidy 3.03, whole-genome doublings 1.
